Surgical pathology report (de-identified scan), TCGA case TCGA-US-A77E, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-US-A77E-01A (Primary Tumor).

[page 1 of 5]
ICD O-3

Adenocarcinoma NOS
8/40/13

Site Pancreas head
25.0
JW 8/20/13

Received

Lab No.

SPECIMEN TYPE: Whipples

AMENDED REPORT

CLINICAL NOTES:

Whipple's specimen. Pancreatic Ca. Periportal lymph node. PeriSMA lymph node. Pericoeliac axis tissue. PeriSMA neural plexus. Peripancreatic lymph node. Perihepatic tissue. Cyst wall. Liver. From Whipple's procedure.

FROZEN SECTION OPINION: Common bile duct margin is clear and the neck margin there is tumour 1.3mm to diathermied margin. (Message to

MACROSCOPIC:

SYNOPTIC REPORT FOR WHIPPLE'S RESECTION

MACROSCOPIC:

A) The specimen was received fresh from theatres for frozen section opinion and consists of a Whipple's specimen.
Specimen labelled: Whipple's specimen.

Specimen Type:

Pancreaticoduodenectomy (Whipple's resection), partial pancreatectomy

Specimen dimensions:

Length of duodenum: 190mm

Length of lesser curve of stomach: 30mm

Length of greater curve of stomach: 60mm

Size of gallbladder: 80mm in length and up to 30mm in maximum diameter..

Wall thickness of gallbladder: 2mm

Calculi in gallbladder: Not present.

Size of and weight of spleen: N/A

Length of bile duct: 55mm

Maximum diameter of bile duct: 14mm

Size of pancreas: 40 x 45 x 40mm

Location of stent: Not present.

Tumour location:

Tumour:

Configuration: Infiltrative

Description: Pale and glistening cut surface with macroscopic mucin.

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

COPIES

Page 1 of 5

Printed:

Where 'Collected' Indicates Rec:

[page 2 of 5]
Received

Lab No

SPECIMEN TYPE: Whipples

Tumour Size:

Greatest dimension: 35mm

Distance of tumour to margins:

Pancreatic neck: On frozen section is 1.2mm

Periuncinate soft tissue: 5mm

Posterior retroperitoneal: 10mm

Portal vein bed: There is vein overlying the portal vein bed margin. The vein appears to be involved. Tumour is seen extending to the portal vein bed and involving the overlying vein wall.

Anterior pancreatic capsule: >10mm

Common bile duct: >30mm

Proximal intestinal/gastric: 70mm

Distal intestinal margin: 140mm

Proximal pancreatic margin (applicable to distal pancreatectomies only):

Additional gross pathologic findings:

Chronic pancreatitis is present. There is a 12mm polyp within the duodenum.

The stomach and gallbladder are otherwise unremarkable.

The portal vein bed and overlying vein have been inked red, the periuncinate soft tissue margin has been inked black.

Blocks 1 to 6 - frozen section

Block 1 - common bile duct margin

Blocks 2 to 6 - pancreatic neck margin in longitudinal section

Blocks 7 and 8 - sections through the portal vein bed and overlying vein

Blocks 9 to 11 - sections through the periuncinate soft tissue margin

Block 12 - intestinal margins

Block 13 - a 12mm polyp from the duodenum

Block 14- sections of gallbladder

Block 15 - a section of tumour

Block 16 - one lymph node

Block 17 - three lymph nodes

Representative sections in 17 blocks.

B) 'Periportal lymph node'. The specimen consists of a piece of fibrofatty tissue 30mm in maximum extent. All embedded in one block.

C) 'PeriSMA lymph node'. The specimen consists of a lymph node 12mm in maximum extent. All embedded in one block.

D) 'Pericoeliac axis tissue'. The specimen consists of a piece of fibrofatty

100

Page 2 of 5

Printed

Where 'Collected' indicates Rec:

[page 3 of 5]
Received

Lab No

A
T
H
O
L
O
G
Y

SPECIMEN TYPE: Whipples

tissue 20mm in maximum extent. All embedded in one block.

E) 'PeriSMA neuroplexus'. The specimen consists of two pieces of tan tissue 5 and 7mm in maximum extent. All embedded in one block.

F) 'Peripancreatic lymph node'. The specimen consists of two pieces of fibrofatty tissue 25 and 5mm in maximum extent. All embedded in one block.

G) 'Perihepatic tissue'. The specimen consists of a piece of tan tissue 20mm in maximum extent. All embedded in one block.

H) 'Cyst wall'. The specimen consists of a fragment of cyst wall 24 x 12mm to a thickness of 3mm. The lining appears glistening. No obvious solid areas are present. Trisected and all embedded in block 1.

I) 'Liver'. The specimen consists of a piece of tan tissue 24 x 15 x 6mm. Serially sectioned and all embedded in blocks 1 and 2.

MICROSCOPIC:

SYNOPTIC REPORT FOR WHIPPLE'S RESECTION:

Tumour location: head

Histologic type (WHO classification): adenocarcinoma

Histologic grade (TNM grading system): Poorly differentiated G3

Tumour size: 35mm (macroscopic measurement).

Extension out of pancreas: present

Small vessel (capillary/lymphatic) invasion: present

Large vessel (vein/artery) invasion: Tumour is present within the media of the portal vein segment

Perineural invasion: present including large nerves in peripancreatic soft tissue of the portal vein bed

Perineural invasion of retroperitoneal (periuncinate) neural plexus: not identified.

Distance of invasive tumour from resection margins:

Pancreatic neck: Involved- tumour is seen within 0.1mm of this margin (Block A2)

Periuncinate soft tissue: 1mm

Posterior retroperitoneal: 10mm

Portal vein bed: tumour is 0.2mm from the soft tissue margin of the portal vein bed (Block A7)

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

Cons

Page 3 of 5

Where 'Collected' indicates Rec:

[page 4 of 5]
Received

Lab No.

SPECIMEN TYPE: Whipples

Common bile duct: >30mm

Lymph nodes from main resection specimen: 2 of 6 lymph nodes are involved by adenocarcinoma

Separately received lymph nodes:

'Periportal lymph node'- Four lymph nodes are present. No evidence of malignancy is seen.

'Pericoeliac axis tissue'- A single lymph node is present. No evidence of malignancy is seen.

'Peripancreatic lymph node'- Fragments of a single lymph node are present. No evidence of malignancy is seen.

'Perihepatic tissue'- A single lymph node is present. There is no evidence of malignancy.

The tissue labelled "Peri SMA (specimen B) is composed primarily of blood and fibrin but does include a small amount of adipose tissue. Some displaced glandular epithelium is present within the blood but no evidence of malignancy is seen.

The tissue labelled "Peri SMA neuroplexus (specimen E) is composed of adipose tissue within which several large nerves are contained. No evidence of malignancy is seen.

Highest grade of Pan-In present: 3

Grade of Pan-In at pancreatic neck resection margin: 1a

Pathologic Staging (pTNM, AJCC 7th edition 2009)

Staged as: Pancreatic ductal carcinoma:

pT: 3

pN: 1

Overall stage: IIB

Additional pathologic comments and findings in other resected organs:

The 12mm duodenal polyp is a tubulovillous adenoma. No high grade dysplasia or carcinoma is present.

Specimen H - The cyst wall is comprised of a cuboidal epithelium overlying fibrous tissue. The appearances are consistent with a simple biliary cyst.

Specimen I - Sections of liver show a subcapsular, well circumscribed area of coagulative necrosis which is contained by a hyalinised fibrous capsule and is

COPIES

Page 4 of 5

Where 'Collected' indicates Rec:

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O
G
Y

[page 5 of 5]
Received

Lab No

SPECIMEN TYPE: Whipples

associated with some inflammation at the margin. The appearance is most in keeping with a solitary necrotic nodule. The cause of such nodules is uncertain. It is thought that they probably represent the end stage of a variety of lesions, with a large proportion representing degenerate haemangiomata. The surrounding liver shows preserved lobular architecture with mild non-specific portal inflammation and focal cholestasis.

SUMMARY:

Tumour type: Adenocarcinoma

Tumour grade: Poorly differentiated (G3)

Tumour location: Head of pancreas

Tumour size: 35mm

Lymph nodes: 2 of 10 lymph nodes contain tumour

Stage: IIB

Margins: Tumour is seen at (within 0.1mm) the pancreatic neck and 0.2mm of the portal vein margin.

REPORTING PATHOLOGIST:

(Electronic Signature)

Cons

Source: NCI Genomic Data Commons file a97b6e28-d6d2-402b-8c72-662078756cd9 (TCGA-US-A77E.28115619-9EDD-41D9-A912-25D3BCB83DC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).